Gene-level copy-number profile of tumor specimen TCGA-FF-8043-01A from TCGA case TCGA-FF-8043, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 70.1 years (25,612 days).
Specimen TCGA-FF-8043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.c62dda8e-e972-4c15-a452-668dc1311a8b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FF-8043-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac8bcdaf-8f7d-4184-928c-fe0f7f5f1875

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 10,710; copy number 2: 40,200; copy number 3: 8,470; copy number 4: 1; copy number 5: 262; copy number 6: 42; copy number 7: 9; copy number 8: 52; copy number 12: 1; copy number 13: 3; copy number 14: 45; copy number 16: 10; copy number 36: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FF-8043-01A-11D-2209-01): tumor purity 0.89, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:57,405,074–57,405,175, 1 gene: RNU6-844P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 433 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,450,520–65,432,637, 126 genes, copy number 5–36 (within-gene range 1–36) (broad region; genes not listed).
- chr2:65,439,838–65,456,571, 1 gene, copy number 8: AC012370.2.
- chr2:66,820,684–67,684,077, 12 genes, copy number 5: DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1.
- chr12:43,835,967–44,389,762, 1 gene, copy number 5 (within-gene range 2–5): TMEM117.
- chr12:44,244,394–50,480,004, 210 genes, copy number 5–7 (broad region; genes not listed).
- chr12:71,125,085–74,728,851, 42 genes, copy number 6 (within-gene range 3–6): TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3.
- chr16:18,926,863–19,553,408, 26 genes, copy number 5 (within-gene range 3–5): AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, LINC02858, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110.
- chr20:17,187,510–17,735,871, 15 genes, copy number 5: RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2.

Autosomal genes at a single copy (total copy number 1): 10,710. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
